Surgical pathology report (de-identified scan), TCGA case TCGA-DR-A0ZL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of Hawaii, specimen TCGA-DR-A0ZL-01A (Primary Tumor).

[page 1 of 3]
Reviewer Initials	Date Review: 10/18/10	
	10/18/10	

Surgical Pathology Report

Patient Name:

Med. Rec. #:

DOB:

Gender:

Physician(s):

CC:

Client:

Location:

Accession #:

Taken:

Received:

Reported:

History/Clinical Dx: Cervical cancer

Postoperative Dx: Pending pathology examination

1CD-0-3

Carcinoma, squamous cell, non-keratinizing, NOS

8072/3

Site: Cervix, NOS C53.9

fw
8/31/11

Specimen(s) Received:

A: Right pelvic lymph node

B: Left ovary and tube

C: Right ovary and tube

D: Left pelvic lymph node

E: Uterus and cervix

F: Left mid common lymph node

G: Right common lymph node

DIAGNOSIS:

A. Right pelvic lymph nodes: Eleven lymph nodes negative for metastasis (0/11)

B. Left ovary and tube: Tube and ovary with no evidence of tumor

C. Right ovary and tube: Tube and ovary with no evidence of tumor

D. Left pelvic lymph nodes: Ten lymph nodes negative for metastasis (0/10)

E. Uterus and cervix: CERVICAL SQUAMOUS CELL CARCINOMA

Tumor Information:

Type of specimen:	TAH-BSO with lymph node sampling
Tumor location:	Cervix
Tumor size:	3.0 x 2.1 x 0.4
Histologic type:	Squamous, non-keratinizing
Histologic grade:	Grade 3, poorly differentiated
Depth of invasion:	0.9 cm
Horizontal extent:	3.0 cm
Lower third of vagina involvement:	Absent
Pelvic wall extension:	Absent
Parametrial invasion:	Absent
Bladder/rectal mucosal extension:	Absent
Lymphovascular invasion:	Not identified
Resection margins:	Clear

Regulatory Statement:

The following statement may be applicable to some of the reagents/antibodies used in developing the above report: This reagent was developed and its performance characteristics determined by the manufacturer and approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as a substitute for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

[page 2 of 3]
Surgical Pathology Report

Lymph node involvement: Absent
Staging information: Tib1, N0

F. Left mid common lymph nodes: Two lymph nodes negative for metastasis (0/2)

G. Right common lymph nodes: One lymph node negative for metastasis (0/1)

Gross Description

- A. Received in formalin labeled "right pelvic lymph node" are multiple fragments of fibroadipose tissue, aggregating up to 5.0 x 3.5 x 1.6 cm. There are eleven lymph nodes grossly identified, largest up to 1.6 x 0.6 x 0.5 cm. Representative sections are submitted in three cassettes as follows:

KEY TO CASSETTES:

A1 - Four lymph nodes
A2 - Four lymph nodes
A3 - Three lymph nodes

- B. Received in formalin labeled "left tube and ovary" is a single piece of soft tan to white tissue, 7 grams, 5.1 x 3.0 x 1.0 cm. There is an apparent ovary, 1.8 x 1.0 x 0.6 cm, which appears unremarkable. There is a tube, 4.6 x 0.5 x 0.5 cm, and appears grossly unremarkable. No lesions are grossly identified. Representative sections are submitted in one cassette.

- C. Received in formalin labeled "right tube and ovary" is a single piece of soft tan to white tissue, 5 grams, 4.1 x 3.5 x 1.8 cm. There is an apparent ovary, 2.1 x 0.8 x 0.8 cm, which appears unremarkable. There is a tube, 4.3 x 0.5 x 0.4 cm. No lesions are grossly identified. Representative sections are submitted in one cassette.

- D. Received in formalin labeled "left pelvic lymph nodes" are multiple fragments of fibroadipose tissue, aggregating 5.5 x 4.6 x 1.7 cm, 10 grams. There are ten lymph nodes grossly identified, largest up to 2.6 x 1.2 x 0.7 cm. Representative sections are submitted as follows:

KEY TO CASSETTES:

D1 - Six lymph nodes
D2 - Two lymph nodes
D3 - Two lymph nodes

- E. Received: In formalin is a previously opened soft tan to white tissue
Labeled: Cervix, uterus
Weight: 83 grams
Size: 8.2 x 8.0 x 3.3 cm
Appearance:
Serosal surface: Smooth with ragged areas. No subserosal bulging
Tumor
Location: Cervical os and extending into the lower uterine segment
Configuration: Fungating, papillary, circumferential
Size: 3.0 x 2.1 x 0.4 cm
Depth of invasion: Appears to involve the lower uterine segment with a superficial involvement, not more than 0.3 cm in thickness
Invasion of contiguous structures: None grossly identified
Distance from margins: 1.6 cm from the cervical margin
Cervix: Appears grossly unremarkable with the exception of above noted
Endometrium: 0.1 cm in thickness. No polyps grossly identified
Myometrium: 1.6 cm in thickness. No areas of adenomyosis grossly identified
Lymph nodes: None grossly identified
Other findings: There are multiple myomas, largest up to 0.6 x 0.5 x 0.4 cm, with a white whorled cut surface

KEY TO CASSETTES:

E1-E2 - Tumor, full thickness
E3 - Tumor

[page 3 of 3]
[REDACTED] **Surgical Pathology Report** [REDACTED]

E4-E5 - Endo/myometrium, myoma

- F. Received in formalin labeled "left mid common lymph node" is a single piece of fibroadipose tissue, 2 grams, 2.5 x 1.4 x 0.6 cm. There are two lymph nodes grossly identified, largest up to 1.3 x 0.6 x 0.4 cm. Submitted in toto in one cassette.
- G. Received in formalin labeled "right common lymph node" is a single segment of fibroadipose tissue, 3 grams, 2.0 x 1.8 x 0.6 cm. There is one lymph node grossly identified, 0.7 x 0.4 x 0.4 cm. Submitted in toto in one cassette.

Microscopic Description

The microscopic findings support the above diagnosis.

[REDACTED]

Source: NCI Genomic Data Commons file f28cce95-2d6a-4b82-a230-6190b69b0219 (TCGA-DR-A0ZL.6CE9D5FB-FE9B-4727-974E-43691EF974F6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).